Somatic mutation profile of tumor specimen 0DJM97 from CCDI case PBBWZU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.6 years (578 days).
Specimen 0DJM97: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf57d6b1-57c1-49f0-b120-d0553105774b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be949d1d-9edb-40e2-968b-87efb297b7ba

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.818A>C p.H273P | Missense Mutation (SNP) | VAF 225/438 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as rs771696085; called by muse, mutect2, varscan2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 480/2040 reads (24%) | catalogued as rs763352877; called by mutect2, varscan2
- NUTM1 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 157/607 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs753682779; called by muse, varscan2
- PLD1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 359/1650 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434314217, COSV60566110, COSV60571560; called by muse, mutect2, varscan2
- SACS | c.2239A>G p.I747V | Missense Mutation (SNP) | VAF 384/1688 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66548360; called by muse, mutect2, varscan2
- SLAMF6 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 135/1273 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs747973864, COSV63588053; called by muse, mutect2, varscan2
- CAGE1 | c.2246A>T p.K749I (on ENST00000512086; = p.K613I on NM_205864.3) | Missense Mutation (SNP) | VAF 71/1006 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- GABRA1 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 94/1060 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.111); called by muse, mutect2
- NEK4 | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 528/1228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK7 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 55/786 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PKHD1 | c.11108A>G p.E3703G | Missense Mutation (SNP) | VAF 184/7314 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SLC34A1 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 40/974 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STON2 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 142/545 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- UNC80 | c.5089C>A p.P1697T | Missense Mutation (SNP) | VAF 693/2831 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP54 | c.1498A>C p.S500R | Missense Mutation (SNP) | VAF 214/1285 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF441 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAR2 | c.30C>T p.G10= | Silent (SNP) | VAF 36/1327 reads (3%) | called by muse, mutect2
- ITPR2 | c.861T>C p.V287= | Silent (SNP) | VAF 259/1646 reads (16%) | catalogued as rs1353903689; called by muse, mutect2, varscan2
- MUC5B | c.5313C>A p.P1771= | Silent (SNP) | VAF 122/740 reads (16%) | catalogued as COSV71593925; called by mutect2, varscan2
- NUTM2A | c.390A>C p.P130= | Silent (SNP) | VAF 42/347 reads (12%) | catalogued as rs1564626019; called by muse, varscan2
- OXR1 | c.208A>C p.R70= (on ENST00000442977 / NM_001198532.1; = p.R69= on NM_018002.3) | Silent (SNP) | VAF 58/2132 reads (3%) | called by muse, mutect2
- PCLO | c.4746C>T p.L1582= | Silent (SNP) | VAF 110/2929 reads (4%) | catalogued as rs776390881; called by muse, mutect2
- PKHD1L1 | c.2572T>C p.L858= | Silent (SNP) | VAF 169/1792 reads (9%) | called by muse, mutect2
- AZU1 | c.*100G>A | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2
- CLVS1 | c.977+88C>A | Intron (SNP) | VAF 82/211 reads (39%) | catalogued as rs1018465324; called by muse, varscan2
- POLQ | c.-66A>T | 5'UTR (SNP) | VAF 69/254 reads (27%) | called by muse, mutect2, varscan2
- TBL3 | c.*1934_*1936dup | 3'UTR (INS) | VAF 76/428 reads (18%) | called by mutect2, varscan2
